Somatic mutation profile of tumor specimen BA2639D (aliquot aq-BA2639D) from BEATAML1.0 case 2368, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 36.5 years (13,345 days).
Specimen BA2639D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b222e0a-5a3a-4708-af9a-efaf54cc3e7c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2214D (Solid Tissue Normal), aliquot aq-BA2214D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d6c6399-fcc6-4e56-8388-0bf24c84e11c

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 1, Silent 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARNTL | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62985710; called by muse, mutect2
- CFTR | c.2438C>A p.S813Y | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLSTN2 | c.630C>A p.D210E | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TPSD1 | c.706del p.V236Sfs*4 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | called by mutect2, pindel, varscan2
- ZP1 | c.1769C>A p.P590H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); called by muse, mutect2
- SNX19 | c.24G>T p.P8= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as COSV99773294; called by muse, mutect2
- CYP4F24P | n.349G>A | RNA (SNP) | VAF 18/45 reads (40%) | catalogued as rs1318031837; called by muse, mutect2, varscan2
- FLT4 | c.2648-134C>G | Intron (SNP) | VAF 32/79 reads (41%) | called by muse, mutect2, varscan2
